Somatic mutation profile of tumor specimen TCGA-EL-A3CM-01A (aliquot TCGA-EL-A3CM-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 64.1 years (23,406 days).
Specimen TCGA-EL-A3CM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da5b1516-0c56-4c0b-b280-5551127a92f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CM-10A (Blood Derived Normal), aliquot TCGA-EL-A3CM-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b0e4515-fd7b-4551-bc1f-7ea32fd93ddd

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCC2 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV64971059; called by muse, mutect2, varscan2
- CIT | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV55863799, COSV55877590; called by muse, mutect2
- DRAM1 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 8/104 reads (8%) | catalogued as COSV51599441; called by muse, mutect2
- IL16 | c.2356G>A p.A786T (on ENST00000302987 / NM_172217.5; = p.A85T on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745776438, COSV57266686; called by muse, mutect2, varscan2
- RAD54L2 | c.820C>A p.H274N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56580449; called by mutect2, varscan2
- RIOK1 | c.87G>C p.L29F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.083); catalogued as COSV53572393, COSV53573070; called by muse, mutect2
- SYCP2L | c.189A>T p.L63F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.139); catalogued as COSV51655944; called by muse, mutect2, varscan2
- ZNF207 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.405); catalogued as COSV58301184; called by muse, mutect2
- EMILIN1 | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.61); called by muse, mutect2
- IL17RC | c.1026C>T p.L342= (on ENST00000295981 / NM_153461.4; = p.L256= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV55974181, COSV55974325; called by muse, mutect2
- SLC35D2 | c.441C>T p.I147= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1219708771, COSV53564007; called by muse, mutect2, varscan2
